Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3D4, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3D4-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Department of Pathology,
Tel: _____

DOB: _____
Physician: _____

Sex: M

Collected: _____

Received: _____

Case type: Surgical Case

Accession: _____

ICD-0-3

Per TSS,
follicular
29990

CQCF: carcinoma, papillary thyroid 8260/3

Site: thyroid, nos C73.9

fw 10/31/11

DIAGNOSIS

(A) LEFT NECK DISSECTION, LEVEL III AND IV:

METASTATIC PAPILLARY THYROID CARCINOMA IN SIX OF TWELVE LYMPH NODES (6/12)
AND IN SOFT TISSUE

Extranodal extension: Present

Path: carcinoma, papillary, follicular variant

8340/3

(B) PORTION, LEFT INFERIOR PARATHYROID:

Parathyroid tissue present

(C) BILATERAL NECK CONTENTS:

METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODES LEFT AND RIGHT SIDES(18/48)

Extranodal extension: Present

(D) BILATERAL TOTAL THYROIDECTOMY, BILATERAL PARATRACHEAL DISSECTION:
PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT

Location: Bilateral including isthmus

Multi-focal: Yes, numerous foci

Size = 4.0 cm largest in Right

Extrathyroidal extension: Present, extending into fibroadipose tissue

Lymphovascular invasion: Present

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN 6 OF 11 LYMPH NODES

Location: Periglandular

Extracapsular extension: Present

(E) RIGHT SUPERIOR PARATRACHEAL CONTENTS:

Parathyroid, negative for tumor

(F) ADDITIONAL RIGHT PARATRACHEAL CONTENTS:

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF FOUR LYMPH NODES (1/4)

Extranodal extension: Absent

GROSS DESCRIPTION

(A) LEFT NECK DISSECTION, LEVEL III AND IV - A piece of fibroadipose tissue (7.0 x 5.0 x 1.3 cm) containing multiple lymph nodes (ranging in size from 0.2 x 2.3 cm). One of the lymph nodes contains a 0.5 cm cyst containing bloody fluid. The cyst has smooth inner surface.

SECTION CODE: A1, two possible lymph nodes; A2, two possible lymph nodes; A3, four possible lymph nodes; A4, two possible lymph nodes; A5, one possible lymph node bisected (with cyst); A6, one possible lymph node bisected; A7, two possible lymph nodes; A8-A10, fibrous tissue with possible lymph nodes.

(B) PORTION, LEFT INFERIOR PARATHYROID - A portion of red-tan tissue (0.5 x 0.2 x 0.1 cm, 5.9 mg). Submitted in toto for frozen section evaluation. Touch preparations performed.

*FS/DX: PARATHYROID TISSUE PRESENT.

Surgical Pathology Report

File under: Pathology

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

Tel:

Fax:

DOB:

Physician:

Sex: M

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

(C) BILATERAL NECK CONTENTS -One pink-red fibrous tissue (16.5 x 10.5 x 1.5 cm) and was oriented into left portion, right portion and inferior portion. In the right portion there are multiple lymph nodes, ranging from 0.4 x 0.4 x 0.3 cm to 2.4 x 2.0 x 1.5 cm. Multiple lymph nodes consist cystic cut surface with tan, light yellow, clear fluid. In left portion, there are three tan-gray lymph nodes, ranging from 0.4 x 0.4 x 0.4 cm to 0.3 x 0.3 x 0.2 cm. In inferior portion multiple lymph nodes are identified ranging from 0.3 x 0.2 x 0.2 cm to (3.5 x 1.8 x 1.0 cm). The lymph nodes are entirely submitted.

SECTION CODE: Left portion lymph node; C1, three possible lymph nodes; right portion lymph node from C2-C18; C2-C5, four possible lymph nodes, each; C6-C8, one lymph node each; C9, C10, one lymph node, serially sectioned; C11, C12, one lymph node, serially sectioned; C13, C14, one lymph node, serially sectioned; C15, C16, one lymph node, serially sectioned; C17, C18, one lymph node, serially sectioned.

Inferior portion from C19-C26; C19, C20, four possible lymph nodes each; C21, two possible lymph nodes; C22, two possible lymph nodes; C23, one possible lymph node; C24, C25, one lymph node, serially sectioned; C26, one possible lymph node.

(D) BILATERAL TOTAL THYROIDECTOMY, BILATERAL PARATRACHEAL DISSECTION - A total thyroidectomy with attached adipose tissue (9.0 x 0.5 x 2.0 cm). A 4.5 x 3.5 x 0.2 cm portion of skeletal muscle fibers is attached to the right anterior lobe of the thyroid. Thyroid overall 8.5 x 5.5 x 2.0 cm, Right lobe, 6.0 x 2.6 x 2.5 cm, and left lobe 5.5 x 2.1 x 1.5 cm. The right upper pole of the thyroid feels nodular with a (4.0 x 2.2 x 1.8 cm) solid and cystic mass in the right upper pole. The remaining thyroid is grossly unremarkable. Dissection of the attached adipose tissue yields twelve possible lymph nodes ranging in size from 0.2 x 0.1 x 0.1 to 1.5 x 1.0 x 1.0 cm. Representative tissue is submitted.

SECTION CODE: D1-D3, representative sections of normal left lobe of thyroid, submitted superior to inferior; D4, isthmus; D5-D9, mass submitted sequentially from superior to inferior, right upper pole; D10, right mid pole, grossly normal thyroid; D11, one lymph node, serially sectioned; D12, one lymph node, serially sectioned; D13, one lymph node, bisected; D14, one lymph node bisected; D15, four possible lymph nodes; D16, four possible lymph nodes.

(E) RIGHT SUPERIOR PARATRACHEAL CONTENTS - A piece of fibroadipose tissue (2.5 x 2.0 x 0.5 cm) containing a lymph node (1.8 x 0.7 x 0.3 cm).

SECTION CODE: E1, one lymph node; E2, remaining adipose tissue (Specimen entirely submitted).

(F) ADDITIONAL RIGHT PARATRACHEAL CONTENTS - A piece of fibroadipose tissue (2.0 x 1.8 x 1.0 cm) containing multiple lymph nodes (0.2 to 1.1 cm in maximum dimension).

SECTION CODE: F1, two possible lymph nodes; F2, one possible lymph node, bisected; F3, one lymph node.

CLINICAL HISTORY

Metastatic Papillary Thyroid Carcinoma.

SNOMED CODES

T-B6000, M-83403, T-C4200, M-80506,

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Entire report and diagnosis completed by:

Surgical Pathology Report

File under: Pathology

Page 2 of 2

Source: NCI Genomic Data Commons file b6f5d87b-188c-4dac-b142-8c7eb74d129d (TCGA-EL-A3D4.4C9E1ABE-DAB5-4935-AD52-187F4EABA7EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).